Gene-level copy-number profile of tumor specimen TCGA-P5-A5EZ-01A from TCGA case TCGA-P5-A5EZ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 39.4 years (14,375 days).
Specimen TCGA-P5-A5EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.2795f7ea-85a9-4d6e-8ef8-c0ceefeeda48.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P5-A5EZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f0dd8a72-042d-4165-862c-cce8b0b331a7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 8,064; copy number 2: 46,932; copy number 3: 4,457; copy number 4: 80; copy number 5: 239; copy number 9: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P5-A5EZ-01A-11D-A27J-01): tumor purity 0.64, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 278 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:3,397,505–17,129,811, 239 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:57,591,174–58,244,865, 39 genes, copy number 9: PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.

Autosomal genes at a single copy (total copy number 1): 5,651. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
